Somatic mutation profile of tumor specimen TCGA-D8-A1Y3-01A (aliquot TCGA-D8-A1Y3-01A-11D-A159-09) from TCGA case TCGA-D8-A1Y3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.1 years (22,317 days).
Specimen TCGA-D8-A1Y3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b5a94f9-c805-4c54-b4a6-49ecd85a0af2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1Y3-10A (Blood Derived Normal), aliquot TCGA-D8-A1Y3-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25df895-051b-4d5a-b52c-4be77efd1f09

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Nonsense Mutation 2, RNA 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGTPBP1 | c.2620C>T p.R874W (on ENST00000357081 / NM_001330701.2; = p.R834W on NM_015239.2) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1418982979, COSV61270623; called by muse, mutect2, varscan2
- APBB1IP | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66133043; called by muse, mutect2, varscan2
- ATP13A1 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52286875; called by muse, mutect2, varscan2
- C2CD2 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as rs767399913, COSV61599708; called by muse, mutect2, varscan2
- CACNA1C | c.5917G>C p.E1973Q (on ENST00000399634 / NM_001167625.1; = p.E1902Q on NM_000719.7) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.954); catalogued as COSV59727772; called by muse, mutect2, varscan2
- DOCK8 | c.4035T>A p.S1345R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV66620709; called by muse, mutect2, varscan2
- DPCD | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780393185, COSV64509075; called by muse, mutect2, varscan2
- DUSP16 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53807998; called by muse, mutect2, varscan2
- ERMP1 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV53037763; called by muse, mutect2, varscan2
- FAM8A1 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52581708; called by muse, mutect2, varscan2
- GRIA1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as COSV53606713; called by muse, mutect2, varscan2
- ILF2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs767092802, COSV62627547; called by muse, mutect2, varscan2
- KIFC1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65737641; called by muse, mutect2, varscan2
- KLHL8 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV56748118; called by muse, mutect2, varscan2
- LIPF | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1028180096, COSV99490427; called by muse, mutect2
- LIPN | c.345G>T p.W115C | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68384070; called by muse, varscan2
- NADK2 | c.1282A>G p.M428V (on ENST00000381937 / NM_001085411.3; = p.M265V on NM_153013.4) | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56936520, COSV56937222; called by muse, varscan2
- NPAT | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs369929633, COSV53723113; called by muse, mutect2, varscan2
- NPR2 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs61758519, COSV61311473; called by muse, mutect2, varscan2
- PCDHGA2 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1475554511, COSV53899507; called by muse, mutect2
- PLD5 | c.1542C>A p.F514L (on ENST00000442594; = p.F452L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100139519, COSV59149409; called by muse, mutect2, varscan2
- PPM1D | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV59956164; called by muse, varscan2
- PTK2 | c.978T>A p.P326= | Splice Region (SNP) | VAF 12/146 reads (8%) | catalogued as COSV100570718; called by muse, mutect2
- SCN11A | c.4093A>G p.S1365G | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1236990869, COSV56571701; called by muse, mutect2, varscan2
- SERPINI2 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs201666797, COSV52986468; called by muse, mutect2
- SIRT2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs199855116, COSV50875469; called by muse, mutect2, varscan2
- SLC7A11 | c.538A>C p.N180H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54930653; called by muse, mutect2, varscan2
- SPRY2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs751166788, COSV65701477; called by muse, mutect2, varscan2
- SRRM4 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57418062; called by muse, mutect2, varscan2
- TICRR | c.4149A>C p.K1383N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as rs938198813, COSV51542298; called by muse, mutect2, varscan2
- TREML1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.943); catalogued as COSV58294831; called by muse, mutect2, varscan2
- TYRO3 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV99777846; called by muse, mutect2
- ULK4 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs767374190, COSV57205700; called by muse, mutect2, varscan2
- VPS33A | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777018517, COSV57357349; called by muse, mutect2, varscan2
- WRN | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs752650803, COSV53301332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF414 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.105); catalogued as rs763516794, COSV55321606; called by muse, mutect2, varscan2
- THBS1 | c.296_298del p.K99del | In Frame Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- CKB | c.141G>A p.T47= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs781697279, COSV62379546; called by muse, mutect2, varscan2
- CUBN | c.8031C>T p.H2677= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1240093362, COSV64717759; called by muse, mutect2, varscan2
- EIF5B | c.1524T>A p.A508= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV56813683; called by muse, mutect2, varscan2
- FOXA2 | c.480G>A p.P160= (on ENST00000377115 / NM_153675.3; = p.P166= on NM_021784.5) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV101008417, COSV65796149; called by muse, mutect2
- FUT4 | c.1146C>T p.T382= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs758199161, COSV62469468; called by muse, mutect2
- KCNK5 | c.510C>T p.G170= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs916995756, COSV63989008; called by muse, mutect2, varscan2
- MC3R | c.429C>T p.Y143= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs148382606; called by muse, mutect2, varscan2
- NRXN2 | c.3141T>C p.N1047= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV55454988; called by muse, mutect2, varscan2
- OR56A4 | c.42G>A p.Q14= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV58110435; called by muse, mutect2, varscan2
- PKHD1L1 | c.7983A>G p.E2661= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as COSV101006573; called by muse, mutect2
- PTPRB | c.1845C>T p.S615= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs765397660, COSV54242792; called by muse, mutect2, varscan2
- RAB14 | c.555T>C p.A185= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as COSV53048130; called by muse, mutect2, varscan2
- TRIM61 | c.252A>G p.R84= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV61418298; called by mutect2, varscan2
- USP32 | c.3294C>T p.P1098= | Silent (SNP) | VAF 87/163 reads (53%) | catalogued as COSV56270214; called by muse, mutect2, varscan2
- DCHS2 | n.3068A>T | RNA (SNP) | VAF 24/94 reads (26%) | catalogued as COSV59728614; called by muse, mutect2, varscan2
